Gene-level copy-number profile of tumor specimen TCGA-D3-A3C1-06A from TCGA case TCGA-D3-A3C1, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS.
Specimen TCGA-D3-A3C1-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.9eb94198-31b3-4aa3-89ed-c8634b1860f9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A3C1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f2f3c44e-0f72-4aa7-9718-75a9599a0d85

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 398; copy number 2: 15,759; copy number 3: 18,665; copy number 4: 23,760; copy number 5: 224; copy number 6: 31; copy number 7: 120; copy number 8: 396; copy number 9: 78; copy number 10: 25; copy number 11: 123; copy number 12: 72; copy number 14: 1; copy number 15: 39; copy number 16: 90; copy number 19: 1; copy number 22: 2; copy number 23: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A3C1-06A-12D-A194-01): tumor purity 0.53, ploidy 3.26, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 457 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:36,147,892–36,196,849, 3 genes, copy number 10 (within-gene range 3–10): MIR580, SKP2, RNU6-1305P.
- chr7:38,257,879–38,335,514, 13 genes, copy number 9: TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7.
- chr7:82,589,848–83,362,266, 5 genes, copy number 12–22: MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1.
- chr7:83,372,652–83,373,096, 1 gene, copy number 22: AC079799.2.
- chr7:88,749,470–88,749,694, 1 gene, copy number 15: AC002127.1.
- chr7:88,794,106–88,795,737, 1 gene, copy number 15: TEX47.
- chr7:96,120,220–99,735,196, 83 genes, copy number 10–16 (within-gene range 8–16) (broad region; genes not listed).
- chr7:104,328,700–104,926,645, 6 genes, copy number 15 (within-gene range 2–15): LHFPL3, EIF4BP6, LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P.
- chr7:106,315,225–106,315,743, 1 gene, copy number 19: LARP1BP2.
- chr7:106,425,278–106,511,544, 1 gene, copy number 12 (within-gene range 2–12): AC005050.3.
- chr7:108,883,975–108,995,029, 4 genes, copy number 15: C7orf66, AC004014.2, AC004014.1, BUB3P1.
- chr7:111,726,110–113,146,330, 26 genes, copy number 23: DOCK4, AC003077.1, DOCK4-AS1, RNA5SP237, AC003080.1, ZNF277, RN7SKP187, AC004112.1, MTND5P8, MTND6P24, MTCYBP24, IFRD1, AC079741.1, AC005192.1, AC079741.2, LSMEM1, NPM1P14, AC002463.1, MIPEPP1, TMEM168, BMT2, HRAT17, AC073346.2, GPR85, AC073346.1, SMIM30.
- chr7:115,789,729–115,833,373, 2 genes, copy number 10: AC093714.2, Y_RNA.
- chr7:117,275,451–117,715,971, 7 genes, copy number 12 (within-gene range 5–12): WNT2, CFTR, AC002465.1, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1.
- chr7:118,214,669–119,179,149, 5 genes, copy number 12 (within-gene range 5–12): ANKRD7, AC002529.1, GTF3AP6, AC092098.1, AC079791.1.
- chr7:133,290,881–133,315,413, 2 genes, copy number 11: MIR6133, AC083875.1.
- chr7:136,025,717–137,847,092, 18 genes, copy number 9: AC024084.1, AC078845.1, Y_RNA, AC009784.1, ZP3P2, AC009264.1, PSMC1P3, CHRM2, MIR490, KRT8P51, AC009517.1, PTN, SNORD81, AC078842.2, AC078842.1, DGKI, AC090498.1, AC009245.1.
- chr7:139,777,051–140,209,671, 6 genes, copy number 9–14 (within-gene range 4–14): TBXAS1, PARP12, KDM7A, Y_RNA, KDM7A-DT, RNU6-797P.
- chr7:140,672,945–140,935,010, 6 genes, copy number 11: ADCK2, NDUFB2, NDUFB2-AS1, BRAF, RNU6-85P, AC006006.1.
- chr7:150,512,559–152,122,340, 59 genes, copy number 10–16 (within-gene range 5–16): STRADBP1, GIMAP7, ALDH7A1P3, GIMAP4, AC069304.3, AC069304.1, GIMAP6, AC069304.2, GIMAP2, GIMAP1, GIMAP1-GIMAP5, GIMAP5, GIMAP3P, BET1P1, TMEM176B, TMEM176A, AOC1, KCNH2, NOS3, ATG9B, ABCB8, AC010973.1, ASIC3, CDK5, SLC4A2, AC010973.3, AC010973.2, FASTK, TMUB1, AGAP3, GBX1, ASB10, IQCA1L, H2BE1, ABCF2-H2BE1, ABCF2, CHPF2, MIR671, SMARCD3, AC021097.1, AC005486.1, NUB1, WDR86, WDR86-AS1, AC005996.1, CRYGN, MIR3907, RN7SL76P, RHEB, ETF1P2, PRKAG2, AC093583.1, PRKAG2-AS1, RNU6-604P, Y_RNA, AC074257.1, GALNTL5, Metazoa_SRP, GALNT11.
- chr7:153,144,313–153,144,588, 1 gene, copy number 9: AC079809.1.
- chr12:53,708,517–53,727,745, 1 gene, copy number 9 (within-gene range 8–9): CALCOCO1.
- chr12:53,746,337–53,762,104, 2 genes, copy number 9: CISTR, AC076968.1.
- chr12:64,404,392–71,927,248, 165 genes, copy number 11–15 (within-gene range 2–15) (broad region; genes not listed).
- chr12:95,217,746–96,875,555, 38 genes, copy number 9 (within-gene range 5–9): VEZT, Y_RNA, CBX3P5, RNU6-808P, MIR331, MIR3685, AC084879.1, AC084879.2, RNU6-735P, AC018475.1, METAP2, USP44, PGAM1P5, Y_RNA, NTN4, AC090001.1, RNU6-247P, LINC02410, SNRPF, CCDC38, AC090001.2, AMDHD1, HAL, AC007298.2, LTA4H, AC007298.1, YPEL5P3, RN7SL88P, LINC02452, ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P, AC125612.1, AC007513.1, RN7SKP11, CFAP54.

Autosomal genes at a single copy (total copy number 1): 36. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
